Somatic mutation profile of tumor specimen ALCH-AE4S-TTP1-A (aliquot ALCH-AE4S-TTP1-A-1-0-D-A678-36) from ALCHEMIST case ALCH-AE4S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.7 years (21,090 days).
Specimen ALCH-AE4S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe725bb9-e74d-440d-b51e-066f9c81d82e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE4S-NB1-B (Blood Derived Normal), aliquot ALCH-AE4S-NB1-B-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2cbf628-6a35-4826-ad69-ee5ac00c3e49

The open-access MAF lists 442 somatic variants for this specimen: 322 protein-altering or splice-affecting, 75 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 287, Silent 75, Intron 24, Nonsense Mutation 14, Splice Site 10, 3'UTR 6, Frame Shift Del 5, RNA 5, Splice Region 4, 5'UTR 4, 5'Flank 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 70/566 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DIS3 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 24/299 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2
- RYR1 | c.7373G>T p.R2458L | Missense Mutation (SNP) | VAF 36/427 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121918594, CM118674, CM981783, COSV62093719; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 55/551 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.8865G>T p.L2955F | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.906); catalogued as COSV101446717; called by muse, mutect2
- ABCG8 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 67/694 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs868807877; called by muse, mutect2
- ACE2 | c.583+1G>C p.X195_splice | Splice Site (SNP) | VAF 9/99 reads (9%) | catalogued as COSV99382616; called by muse, mutect2
- ADAMTS10 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 35/312 reads (11%) | catalogued as COSV54354398; called by muse, mutect2, varscan2
- ADRB2 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100019169; called by muse, mutect2
- AGBL4 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.75); catalogued as rs1304307906; called by muse, mutect2
- AMPH | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 90/827 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs574824661, COSV100343130, COSV57742984; called by muse, mutect2, varscan2
- ANKRD27 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 29/407 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV60131454; called by muse, mutect2
- ARAP2 | c.3427G>T p.G1143C | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394995; called by muse, mutect2
- ARHGAP33 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1182745854; called by muse, mutect2
- ASB10 | c.730C>A p.R244S (on ENST00000420175 / NM_001142459.2; = p.R229S on NM_080871.4) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV51997743, COSV99318781; called by muse, mutect2, varscan2
- ASTN1 | c.1770C>A p.S590R | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs1457570004; called by muse, mutect2
- ATP8B2 | c.1483C>T p.P495S (on ENST00000672630; = p.P462S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs982603302; called by muse, mutect2
- BRINP1 | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.972); catalogued as rs758808562, COSV56295225; called by muse, mutect2, varscan2
- C12orf40 | c.1634A>G p.D545G | Missense Mutation (SNP) | VAF 30/363 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV61136694; called by muse, mutect2
- C8B | c.534G>T p.G178= | Splice Region (SNP) | VAF 67/742 reads (9%) | catalogued as COSV64777626; called by muse, mutect2
- CCL26 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782624721; called by muse, mutect2, varscan2
- CDC14C | c.347C>G p.P116R (on ENST00000428251; = p.P9R on NM_152627.3) | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1213774009; called by muse, mutect2, varscan2
- CDH12 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101203210; called by muse, mutect2, varscan2
- CDK5 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 47/387 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV99876744; called by muse, mutect2
- CDX4 | c.275C>A p.T92K | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); catalogued as rs749168322; called by muse, mutect2, varscan2
- CFAP47 | c.847del p.V283Wfs*25 | Frame Shift Del (DEL) | VAF 25/162 reads (15%) | catalogued as COSV99935278; called by mutect2, pindel*, varscan2
- CHN1 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 38/554 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); catalogued as COSV55033142; called by muse, mutect2
- CHRM3 | c.666C>A p.F222L | Missense Mutation (SNP) | VAF 37/916 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV55087727; called by muse, mutect2
- CLMN | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV54182288; called by muse, mutect2
- COL14A1 | c.3931A>T p.K1311* | Nonsense Mutation (SNP) | VAF 11/237 reads (5%) | catalogued as COSV52865550; called by muse, mutect2
- COL4A5 | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM098946; called by muse, mutect2, varscan2
- CSMD3 | c.5816G>T p.C1939F (on ENST00000297405 / NM_001363185.1; = p.C1835F on NM_052900.3) | Missense Mutation (SNP) | VAF 46/727 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52145731; called by muse, mutect2
- CTAGE1 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV66945224; called by muse, mutect2
- CUX2 | c.3792G>T p.E1264D | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV55651396; called by muse, mutect2
- CXCR1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 42/521 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs371028807; called by muse, mutect2
- DGKB | c.2406C>A p.S802R | Missense Mutation (SNP) | VAF 37/500 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99337672; called by muse, mutect2
- DMD | c.4344+1G>T p.X1448_splice | Splice Site (SNP) | VAF 46/307 reads (15%) | catalogued as rs1172744225; called by muse, mutect2, varscan2
- DST | c.22301G>A p.R7434Q (on ENST00000361203 / NM_001374722.1; = p.R5144Q on NM_015548.5) | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761116868; called by muse, mutect2
- DTL | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs1281584289, COSV100877202; called by muse, mutect2, varscan2
- EFCAB6 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 26/285 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.841); catalogued as rs763425686; called by muse, mutect2
- EPG5 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV56357296; called by muse, mutect2
- EPPK1 | c.4973G>A p.G1658E | Missense Mutation (SNP) | VAF 52/499 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1411621635, COSV73261435; called by muse, mutect2, varscan2
- EVX2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs1474775857, COSV100420821, COSV57963393; called by muse, mutect2
- F2RL2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56972353; called by muse, mutect2, varscan2
- GBP4 | c.1019C>A p.A340E | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV63252809; called by muse, mutect2
- HCN1 | c.2542G>C p.G848R | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57513602; called by muse, mutect2
- HIP1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs1554523975; called by muse, mutect2
- HMGN5 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV63916674; called by muse, mutect2, varscan2
- HUWE1 | c.4976C>T p.T1659M | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs1556971958, COSV53366811; called by muse, mutect2
- IGDCC4 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs560887461, COSV61537226; called by muse, mutect2
- IGHA2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs1357557134; called by muse, mutect2
- IGHV3-38 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.233); catalogued as rs756140430; called by muse, mutect2
- IRGQ | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV60671008; called by muse, mutect2
- IRX1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.346); catalogued as COSV57358951; called by muse, mutect2, varscan2
- JAML | c.355C>G p.R119G (on ENST00000356289 / NM_001098526.2; = p.R109G on NM_153206.3) | Missense Mutation (SNP) | VAF 50/698 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52629872; called by muse, mutect2
- KLHL36 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as rs942543634; called by muse, mutect2
- KLHL7 | c.1530G>T p.M510I (on ENST00000339077 / NM_001031710.3; = p.M462I on NM_018846.5) | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100177565; called by muse, mutect2, varscan2
- KRT33A | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 26/513 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99145071; called by muse, mutect2
- KRTAP6-1 | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 19/291 reads (7%) | PolyPhen benign (0.027); catalogued as COSV58168701; called by muse, mutect2
- LOX | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV50241067; called by muse, mutect2
- LRP1B | c.7780G>T p.V2594F | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs1363852530, COSV67244458; called by muse, mutect2
- LRRC7 | c.4400G>T p.R1467L (on ENST00000651989 / NM_001370785.2; = p.R1387L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/555 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99227906; called by muse, mutect2, varscan2
- LRRIQ1 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV101280737; called by muse, mutect2
- MAGEC2 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99909764; called by muse, mutect2, varscan2
- MMRN1 | c.2906C>A p.P969Q | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV53338104, COSV99306646; called by muse, mutect2
- MYO7B | c.1152G>T p.R384S | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0.383); catalogued as COSV101268308; called by muse, mutect2
- NALCN | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV51915483; called by muse, mutect2
- NAT16 | c.548del p.L183Wfs*174 | Frame Shift Del (DEL) | VAF 20/180 reads (11%) | catalogued as rs1322902549; called by mutect2, pindel, varscan2
- NAV2 | c.2556G>T p.R852S (on ENST00000396087 / NM_001244963.2; = p.R829S on NM_145117.5) | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.37); catalogued as COSV62323162; called by muse, mutect2
- NIFK | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 24/260 reads (9%) | catalogued as COSV53534316; called by muse, mutect2
- OCA2 | c.2158C>A p.R720S | Missense Mutation (SNP) | VAF 70/675 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as CM992196; called by muse, mutect2, varscan2
- OR2G3 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 12/257 reads (5%) | catalogued as COSV60682389; called by muse, mutect2
- OR2J3 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV65849157; called by muse, mutect2, varscan2
- OR2T33 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 76/784 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58817995; called by muse, varscan2
- OR51L1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 35/491 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV58624743, COSV58625749; called by muse, mutect2
- OR52A5 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1274783284, COSV56617039; called by muse, mutect2
- OTOF | c.3332C>A p.P1111Q (on ENST00000272371 / NM_194248.3; = p.P364Q on NM_004802.4) | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs141972928; called by muse, mutect2, varscan2
- PARD3B | c.3382C>T p.R1128C (on ENST00000406610 / NM_001302769.2; = p.R1059C on NM_057177.7) | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1174053056; called by muse, mutect2
- PCDH15 | c.4095G>T p.K1365N | Missense Mutation (SNP) | VAF 70/725 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57267577, COSV57339717; called by muse, mutect2, varscan2
- PCDH17 | c.290G>C p.R97P | Missense Mutation (SNP) | VAF 37/710 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV64975942; called by muse, mutect2
- PCDHA2 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 67/732 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV100973801, COSV65366979; called by muse, mutect2
- PCDHA8 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV65340421, COSV65341310; called by muse, mutect2, varscan2
- PCDHA8 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 74/457 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV65336409; called by muse, mutect2, varscan2
- PCDHB4 | c.2165G>C p.G722A | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV99521747; called by muse, mutect2
- PCDHGA1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as COSV65298723, COSV65299069; called by muse, mutect2
- PCF11 | c.2498G>C p.R833P | Missense Mutation (SNP) | VAF 68/608 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV53529547, COSV53530301; called by muse, mutect2, varscan2
- PDE6C | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 127/762 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.895); catalogued as COSV101008622, COSV65116401; called by muse, mutect2, varscan2
- PKHD1 | c.11249C>T p.S3750L | Missense Mutation (SNP) | VAF 15/437 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV64399068; called by muse, mutect2
- PLAAT1 | c.818A>G p.Y273C (on ENST00000650797; = p.Y168C on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs750466387; called by muse, mutect2
- PLEKHA7 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 35/321 reads (11%) | catalogued as rs372267404; called by muse, mutect2, varscan2
- PTPRB | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 35/497 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs112249725; called by muse, mutect2
- PTPRD | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 49/636 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61928643; called by muse, mutect2
- PTPRZ1 | c.2863G>T p.G955C | Missense Mutation (SNP) | VAF 54/530 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as rs763354591, COSV66444072; called by muse, mutect2
- RGS8 | c.310A>G p.K104E (on ENST00000367556 / NM_001369564.2; = p.K122E on NM_033345.3) | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV51116479; called by muse, mutect2, varscan2
- SIPA1L2 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 26/792 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301775123, COSV53394039; called by muse, mutect2
- SLC24A4 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV54117014, COSV54118409; called by muse, mutect2
- SLC39A10 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV62767732; called by muse, mutect2
- STYXL2 | c.2438G>T p.R813I | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV54805980; called by muse, mutect2, varscan2
- SYCP2 | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV62765698; called by muse, mutect2
- TECRL | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.09); catalogued as COSV67090572; called by muse, mutect2
- TEX47 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1226394222; called by muse, mutect2
- TGIF2LX | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 64/482 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV52213391, COSV52215223; called by muse, mutect2, varscan2
- TYK2 | c.2110G>T p.G704C | Missense Mutation (SNP) | VAF 31/322 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99314065; called by muse, mutect2
- UNC80 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.518); catalogued as rs1228713310; called by muse, mutect2
- UPK3B | c.443C>T p.P148L (on ENST00000257632; = p.P93L on NM_001347684.2) | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.661); catalogued as rs765374716, COSV57536652; called by muse, mutect2, varscan2
- WDR64 | c.2980C>A p.P994T | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs1334367822, COSV63800465; called by muse, mutect2, varscan2
- WFDC1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs766149943, COSV54745719; called by muse, mutect2, varscan2
- ZDHHC8 | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1397959951, COSV57713503; called by muse, mutect2, varscan2
- ZEB1 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.802); catalogued as COSV100314223; called by muse, mutect2, varscan2
- ZKSCAN3 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 92/659 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1264203811; called by muse, mutect2, varscan2
- ZNF658 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 58/608 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs375581570; called by muse, mutect2
- ZNF736 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1299952507; called by muse, mutect2
- ACAN | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTS14 | c.616G>C p.V206L | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADCY4 | c.2291G>T p.W764L | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- ADGRA3 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- AHSA1 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2
- ANKRD18B | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ANOS1 | c.519A>T p.Q173H | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1IP | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2
- ATF6B | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- AXDND1 | c.2561G>T p.S854I | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- BCL6 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 55/639 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRSK2 | c.470T>C p.I157T | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- BTBD18 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BTN1A1 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 98/659 reads (15%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C3orf20 | c.156A>T p.E52D | Missense Mutation (SNP) | VAF 46/585 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); called by muse, mutect2
- C6 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 37/486 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CBX2 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2
- CCDC154 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); called by muse, mutect2
- CDH10 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 103/626 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- CDH8 | c.1756C>A p.L586M | Missense Mutation (SNP) | VAF 69/1196 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.091); called by muse, mutect2
- CDNF | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 15/355 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- CFAP54 | c.6332T>A p.L2111Q | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CFH | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 52/432 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, varscan2
- CHPF2 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 80/573 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CILP | c.3540G>T p.Q1180H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); called by muse, varscan2
- CKAP2 | c.682G>T p.V228L (on ENST00000378037 / NM_001098525.2; = p.V227L on NM_018204.5) | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2
- CLMN | c.1298A>G p.Y433C | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by muse, mutect2
- CLSTN2 | c.1520C>A p.T507N | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2
- CLVS1 | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CMKLR1 | c.815G>T p.C272F (on ENST00000312143 / NM_001142344.2; = p.C270F on NM_004072.3) | Missense Mutation (SNP) | VAF 53/702 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTLN | c.2246G>T p.G749V | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- CNTNAP2 | c.2786G>T p.G929V | Missense Mutation (SNP) | VAF 103/810 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CNTNAP5 | c.1128C>G p.S376R | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL11A2 | c.4595G>C p.G1532A (on ENST00000341947 / NM_080680.3; = p.G1425A on NM_080679.2) | Missense Mutation (SNP) | VAF 56/692 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.321); called by muse, mutect2
- COL6A5 | c.5015T>A p.F1672Y | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2
- COL7A1 | c.847-2A>T p.X283_splice | Splice Site (SNP) | VAF 52/612 reads (8%) | called by muse, mutect2
- CPT1A | c.1151C>G p.T384S | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); called by muse, mutect2
- CREBBP | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 52/736 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.018); called by muse, mutect2
- CSF1R | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0.08); called by muse, mutect2
- CSMD1 | c.5294G>T p.R1765L (on ENST00000520002; = p.R1764L on NM_033225.6) | Missense Mutation (SNP) | VAF 54/712 reads (8%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); called by muse, mutect2
- CSMD3 | c.9913A>T p.K3305* (on ENST00000297405 / NM_001363185.1; = p.K3136* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 74/508 reads (15%) | called by muse, mutect2, varscan2
- CTSC | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 92/563 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CWC27 | c.1369A>T p.R457W | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CWC27 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.952); called by muse, mutect2
- CYP4F12 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- DCAF12L1 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIP2A | c.3280A>T p.S1094C | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DNAH1 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH5 | c.13490A>T p.Q4497L | Missense Mutation (SNP) | VAF 40/563 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNHD1 | c.14198C>T p.T4733I | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK1 | c.3388A>T p.T1130S | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- DPYS | c.63G>C p.E21D | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- DRD3 | c.383+2T>C p.X128_splice | Splice Site (SNP) | VAF 15/263 reads (6%) | called by muse, mutect2
- DUSP15 | c.100A>T p.I34F (on ENST00000278979 / NM_001320479.1; = p.I37F on NM_080611.4) | Missense Mutation (SNP) | VAF 40/477 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1777G>T p.G593* | Nonsense Mutation (SNP) | VAF 40/491 reads (8%) | called by muse, mutect2
- ENPP1 | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 88/910 reads (10%) | called by muse, mutect2
- EPS15L1 | c.2164+1G>A p.X722_splice | Splice Site (SNP) | VAF 20/413 reads (5%) | called by muse, mutect2
- ESYT2 | c.2701G>T p.A901S (on ENST00000613624; = p.A825S on NM_020728.3) | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- F12 | c.1018+2T>A p.X340_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | called by mutect2, varscan2
- FAM171A1 | c.2034G>T p.L678F | Missense Mutation (SNP) | VAF 68/510 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- FAM181B | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FBXL13 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2
- FDXR | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/131 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); called by muse, mutect2
- FSTL1 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GABBR2 | c.2728G>T p.V910L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- GALNT16 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GBX1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- GDAP1L1 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 34/484 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- GFAP | c.1263G>C p.Q421H | Missense Mutation (SNP) | VAF 30/509 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2
- GLI2 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 22/231 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GPCPD1 | c.1700G>T p.R567I | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- HEATR5A | c.5080T>C p.C1694R | Missense Mutation (SNP) | VAF 66/646 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HOXB2 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSD17B7P2 | n.314+5A>T | Splice Region (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- HSF5 | c.1444C>A p.Q482K | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2
- HTR4 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 24/330 reads (7%) | PolyPhen possibly damaging (0.578); called by muse, mutect2
- IGHV3-20 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 23/658 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.848); called by muse, mutect2
- IGKV1D-42 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- INSC | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 27/296 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- INSR | c.1461G>T p.K487N | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IRX4 | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 94/492 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- ITGA2B | c.1567G>T p.G523* | Nonsense Mutation (SNP) | VAF 89/915 reads (10%) | called by muse, mutect2
- KCNH4 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCP | c.3032del p.P1011Lfs*14 (on ENST00000620378; = p.P1071Lfs*14 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 14/125 reads (11%) | called by mutect2, pindel, varscan2
- KDR | c.3660C>A p.I1220= | Splice Region (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- KEAP1 | c.200T>A p.M67K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KIF1A | c.776del p.G259Efs*17 | Frame Shift Del (DEL) | VAF 9/100 reads (9%) | called by mutect2, varscan2
- KLKB1 | c.1899G>C p.Q633H | Missense Mutation (SNP) | VAF 26/798 reads (3%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.173); called by muse, mutect2
- KMO | c.222+1G>T p.X74_splice | Splice Site (SNP) | VAF 36/208 reads (17%) | called by muse, mutect2, varscan2
- KRT14 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2
- KRT14 | c.769A>T p.M257L | Missense Mutation (SNP) | VAF 23/372 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.09); called by muse, mutect2
- KRT38 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2
- LAMA5 | c.3320G>T p.G1107V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCE3D | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 14/453 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- LOXHD1 | c.4530G>T p.T1510= | Splice Region (SNP) | VAF 21/227 reads (9%) | called by muse, mutect2, varscan2
- LRRC71 | c.1632del p.I545Sfs*24 | Frame Shift Del (DEL) | VAF 29/244 reads (12%) | called by mutect2, pindel, varscan2
- LRRN1 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 29/384 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2
- LYPD2 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 39/461 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2
- MAGEA10 | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 31/266 reads (12%) | called by muse, mutect2, varscan2
- MAGEA12 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- MAGEA12 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, varscan2
- MGAM2 | c.4037C>A p.A1346D | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- MRC1 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 50/928 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- MRPS33 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 76/862 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2
- MSTN | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2
- MUC16 | c.8528C>A p.T2843K | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2
- MYBPH | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYLK3 | c.2430C>A p.N810K | Missense Mutation (SNP) | VAF 23/329 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- MYT1L | c.2224C>A p.R742S | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); called by muse, mutect2
- NACA | c.117A>C p.E39D | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2
- NAGLU | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 33/628 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NCKAP5 | c.5641C>A p.L1881M | Missense Mutation (SNP) | VAF 42/531 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.323); called by muse, mutect2
- NCKAP5 | c.1258G>C p.V420L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEK1 | c.1065G>T p.R355S | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- NIM1K | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 73/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.4221A>G p.I1407M | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2
- NUF2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR13C3 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 80/776 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR13C9 | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR1E1 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- OR1J2 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 17/536 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- OR4A47 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2
- OR52E2 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- OTOP3 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.309); called by mutect2, varscan2
- PAK5 | c.2084T>A p.L695H | Missense Mutation (SNP) | VAF 28/479 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PARD3B | c.3383G>T p.R1128L (on ENST00000406610 / NM_001302769.2; = p.R1059L on NM_057177.7) | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.07); called by muse, mutect2
- PATJ | c.385-1G>T p.X129_splice | Splice Site (SNP) | VAF 20/162 reads (12%) | called by muse, varscan2
- PAXIP1 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PCDHA2 | c.975A>T p.K325N | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.135); called by muse, mutect2
- PCDHB11 | c.1915A>T p.R639W | Missense Mutation (SNP) | VAF 43/736 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHB6 | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 50/583 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2
- PDZD2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 134/620 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PEG3 | c.4031G>A p.S1344N | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PEG3 | c.4030A>T p.S1344C | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- PEX6 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- PHGR1 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 28/236 reads (12%) | PolyPhen probably damaging (0.998); called by muse, varscan2
- PLBD2 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PLCB4 | c.2928G>T p.E976D | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); called by muse, mutect2
- PLD1 | c.2184T>A p.H728Q | Missense Mutation (SNP) | VAF 32/431 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- PLD5 | c.1372G>C p.G458R (on ENST00000442594; = p.G396R on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHA5 | c.2890A>T p.R964* | Nonsense Mutation (SNP) | VAF 25/414 reads (6%) | called by muse, mutect2
- PLXNA4 | c.2680G>A p.V894I | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.629); called by muse, mutect2
- PLXNA4 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 58/418 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- POTEA | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPFIA2 | c.2228C>A p.T743K | Missense Mutation (SNP) | VAF 48/779 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- PPM1L | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 25/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP4R3C | c.2150C>A p.P717Q | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2
- PRAMEF14 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 41/883 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- PRKAR2A | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2
- PRKAR2B | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, varscan2
- PRPF38B | c.673G>T p.V225F | Missense Mutation (SNP) | VAF 15/425 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PSG3 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 27/765 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PSG9 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2
- PTPRD | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.411); called by muse, mutect2
- RAB3GAP2 | c.3259A>T p.R1087W | Missense Mutation (SNP) | VAF 17/425 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- RALYL | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2
- RASGRP4 | c.1528C>A p.R510S | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.044); called by muse, mutect2
- REV3L | c.8611G>C p.E2871Q | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RNF8 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 42/598 reads (7%) | called by muse, mutect2
- ROBO2 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 38/556 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- RPS6KA6 | c.1489A>T p.T497S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- RYR1 | c.1822T>C p.C608R | Missense Mutation (SNP) | VAF 86/908 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN3A | c.3476C>G p.P1159R | Missense Mutation (SNP) | VAF 58/882 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.745); called by muse, mutect2
- SCN5A | c.703+1G>T p.X235_splice | Splice Site (SNP) | VAF 26/262 reads (10%) | called by muse, mutect2
- SCN9A | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCPEP1 | c.313T>A p.W105R | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEL1L2 | c.210A>T p.K70N | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- SERPINA10 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 22/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SHLD1 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- SLC12A3 | c.503T>A p.I168N | Missense Mutation (SNP) | VAF 40/470 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC39A8 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- SLC5A11 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLF1 | c.2289C>G p.D763E | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLFN11 | c.2037C>A p.D679E | Missense Mutation (SNP) | VAF 50/690 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2
- SLITRK3 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPHKAP | c.33-1G>T p.X11_splice | Splice Site (SNP) | VAF 24/333 reads (7%) | called by muse, mutect2
- SSBP3 | c.629G>T p.G210V (on ENST00000371320 / NM_145716.4; = p.G190V on NM_018070.5) | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SSH2 | c.4051G>A p.G1351S | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.054); called by muse, mutect2
- SSX5 | c.458dup p.T154Dfs*17 (on ENST00000347757 / NM_175723.1; = p.T195Dfs*17 on NM_021015.4) | Frame Shift Ins (INS) | VAF 23/164 reads (14%) | called by mutect2, pindel, varscan2
- ST3GAL5 | c.549C>A p.N183K (on ENST00000377332; = p.N223K on NM_003896.4) | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SUN1 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SVOP | c.355A>G p.S119G | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.697); called by muse, mutect2
- SYNE1 | c.743C>G p.T248R (on ENST00000367255 / NM_182961.4; = p.T255R on NM_033071.3) | Missense Mutation (SNP) | VAF 36/604 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- SYT9 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TDRD6 | c.2589G>T p.K863N | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- TEDDM1 | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 34/954 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- TMEM160 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMPRSS15 | c.1222G>C p.G408R | Missense Mutation (SNP) | VAF 44/600 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- TNFAIP1 | c.74T>A p.L25* | Nonsense Mutation (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- TRHDE | c.1225T>C p.W409R | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM41 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 32/706 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.53); called by muse, mutect2
- TRIM48 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 73/913 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.211); called by muse, mutect2
- TRPV5 | c.2122A>C p.T708P | Missense Mutation (SNP) | VAF 68/574 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TSHR | c.2134C>A p.P712T | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC17 | c.2441C>G p.P814R | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- TTC23L | c.50G>C p.W17S | Missense Mutation (SNP) | VAF 121/556 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC34 | c.2883C>G p.D961E | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TTLL7 | c.1571A>T p.K524M | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.79627A>T p.S26543C (on ENST00000591111; = p.S19119C on NM_003319.4) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | PolyPhen possibly damaging (0.874); called by muse, mutect2
- TTN | c.68254C>A p.Q22752K (on ENST00000591111; = p.Q15328K on NM_003319.4) | Missense Mutation (SNP) | VAF 26/336 reads (8%) | PolyPhen benign (0.124); called by muse, mutect2
- UHRF2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2
- URB2 | c.3724G>T p.D1242Y | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- USHBP1 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- WASHC2A | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 37/408 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZFHX4 | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 35/402 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2
- ZFP42 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 37/635 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF226 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF385D | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.191); called by muse, mutect2
- ZNF418 | c.660A>T p.Q220H | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZNF831 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ACTN2 | c.627A>T p.I209= | Silent (SNP) | VAF 69/444 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.5499C>A p.A1833= | Silent (SNP) | VAF 24/303 reads (8%) | called by muse, mutect2
- ADAMTS9 | c.4798C>A p.R1600= | Silent (SNP) | VAF 54/605 reads (9%) | catalogued as COSV55786573, COSV55787118; called by muse, mutect2
- ADCY2 | c.501C>T p.S167= | Silent (SNP) | VAF 104/534 reads (19%) | called by muse, mutect2, varscan2
- AICDA | c.354C>T p.D118= | Silent (SNP) | VAF 62/611 reads (10%) | catalogued as COSV99984344; called by muse, mutect2, varscan2
- ANKRD55 | c.384C>T p.R128= | Silent (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- APBB1IP | c.1923C>T p.G641= | Silent (SNP) | VAF 24/601 reads (4%) | called by muse, mutect2
- ASXL3 | c.4461G>T p.L1487= | Silent (SNP) | VAF 29/330 reads (9%) | called by muse, mutect2
- BCL7B | c.186G>A p.S62= | Silent (SNP) | VAF 19/472 reads (4%) | catalogued as rs144017861; called by muse, mutect2
- BPIFB1 | c.933T>A p.P311= | Silent (SNP) | VAF 27/353 reads (8%) | called by muse, mutect2
- BRAT1 | c.375G>A p.Q125= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- C4orf54 | c.3228C>T p.F1076= | Silent (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- C8A | c.429T>C p.Y143= | Silent (SNP) | VAF 47/1064 reads (4%) | catalogued as rs1471547257; called by muse, mutect2
- CALCB | c.306C>A p.G102= | Silent (SNP) | VAF 34/465 reads (7%) | called by muse, mutect2
- CDK5 | c.465C>T p.V155= | Silent (SNP) | VAF 47/398 reads (12%) | called by muse, mutect2
- CLRN1 | c.336C>T p.T112= (on ENST00000327047 / NM_174878.3; = p.T36= on NM_052995.2) | Silent (SNP) | VAF 41/604 reads (7%) | catalogued as rs565400473; called by muse, mutect2
- CNNM3 | c.756G>A p.A252= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- COL26A1 | c.1182A>G p.P394= (on ENST00000313669 / NM_001278563.3; = p.P392= on NM_133457.4) | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- COL6A6 | c.3474G>T p.V1158= | Silent (SNP) | VAF 43/418 reads (10%) | called by muse, mutect2, varscan2
- CYFIP2 | c.3204G>A p.E1068= (on ENST00000616178 / NM_001291722.2; = p.E1043= on NM_014376.4) | Silent (SNP) | VAF 23/472 reads (5%) | catalogued as rs1198100231; called by muse, mutect2
- DCAF4L2 | c.321G>T p.L107= | Silent (SNP) | VAF 32/481 reads (7%) | called by muse, mutect2
- DPRX | c.555T>C p.S185= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- EEFSEC | c.942G>T p.A314= | Silent (SNP) | VAF 38/398 reads (10%) | catalogued as COSV54621385; called by muse, mutect2
- EFNA3 | c.321C>A p.R107= | Silent (SNP) | VAF 36/245 reads (15%) | called by muse, mutect2, varscan2
- FAM135B | c.645G>T p.G215= | Silent (SNP) | VAF 15/269 reads (6%) | catalogued as COSV52713234; called by muse, mutect2
- FERD3L | c.378G>A p.R126= | Silent (SNP) | VAF 48/760 reads (6%) | called by muse, mutect2
- FLNC | c.723G>T p.V241= | Silent (SNP) | VAF 78/663 reads (12%) | called by muse, mutect2, varscan2
- FSCN3 | c.1395C>T p.L465= | Silent (SNP) | VAF 49/398 reads (12%) | catalogued as rs1363000096; called by muse, mutect2, varscan2
- GLI3 | c.2223C>T p.L741= | Silent (SNP) | VAF 39/946 reads (4%) | catalogued as rs1280655354, COSV67893855; called by muse, mutect2
- GLI4 | c.42G>A p.P14= | Silent (SNP) | VAF 27/225 reads (12%) | catalogued as rs747024865; called by muse, mutect2, varscan2
- GPRC5B | c.915C>A p.P305= | Silent (SNP) | VAF 38/487 reads (8%) | called by muse, mutect2
- HK2 | c.2115G>T p.V705= | Silent (SNP) | VAF 74/550 reads (13%) | called by muse, mutect2, varscan2
- HOXD12 | c.480T>A p.P160= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- ITFG1 | c.546G>A p.Q182= | Silent (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- KCNA10 | c.687C>A p.S229= | Silent (SNP) | VAF 18/294 reads (6%) | called by muse, mutect2
- KPRP | c.1440C>A p.P480= | Silent (SNP) | VAF 23/360 reads (6%) | called by muse, mutect2
- KRT5 | c.1110G>A p.Q370= | Silent (SNP) | VAF 69/659 reads (10%) | catalogued as rs748377756; called by muse, mutect2, varscan2
- LCE4A | c.264G>T p.G88= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2
- LRP1B | c.288G>T p.L96= | Silent (SNP) | VAF 34/400 reads (9%) | called by muse, mutect2
- MAGEC1 | c.54C>T p.S18= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- MAPK11 | c.186G>C p.L62= | Silent (SNP) | VAF 33/259 reads (13%) | called by muse, mutect2, varscan2
- MC3R | c.795C>A p.I265= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV54763809; called by muse, mutect2
- OR2T12 | c.90G>T p.L30= | Silent (SNP) | VAF 47/278 reads (17%) | catalogued as COSV100527868; called by muse, mutect2, varscan2
- OR6F1 | c.342C>A p.L114= | Silent (SNP) | VAF 64/389 reads (16%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1056G>T p.L352= | Silent (SNP) | VAF 32/448 reads (7%) | called by muse, mutect2
- PCDHAC2 | c.2169C>T p.I723= | Silent (SNP) | VAF 22/632 reads (3%) | catalogued as COSV53836896; called by muse, mutect2
- PDE3A | c.1665C>A p.A555= | Silent (SNP) | VAF 46/858 reads (5%) | called by muse, mutect2
- PIEZO1 | c.894C>T p.S298= | Silent (SNP) | VAF 27/281 reads (10%) | catalogued as rs1420327605; called by muse, mutect2
- PLCB4 | c.1293C>A p.L431= | Silent (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- PLEC | c.13377C>T p.I4459= (on ENST00000322810 / NM_201380.4; = p.I4349= on NM_000445.5) | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as rs201042249; called by muse, mutect2
- PLPPR2 | c.501G>C p.T167= | Silent (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- PLPPR4 | c.1950A>G p.K650= | Silent (SNP) | VAF 11/307 reads (4%) | called by muse, mutect2
- PSG3 | c.879G>A p.R293= | Silent (SNP) | VAF 27/760 reads (4%) | called by muse, mutect2
- RBMXL3 | c.735G>A p.P245= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs782396163; called by muse, mutect2, varscan2
- RHOBTB3 | c.870C>T p.P290= | Silent (SNP) | VAF 23/246 reads (9%) | called by muse, mutect2
- SEMA4D | c.471C>T p.P157= | Silent (SNP) | VAF 23/590 reads (4%) | called by muse, mutect2
- SHANK1 | c.4548G>T p.P1516= | Silent (SNP) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- SLC45A2 | c.1521G>C p.V507= | Silent (SNP) | VAF 206/979 reads (21%) | catalogued as rs1325153463; called by muse, mutect2, varscan2
- SLITRK5 | c.210C>A p.I70= | Silent (SNP) | VAF 39/374 reads (10%) | catalogued as COSV61523608; called by muse, mutect2, varscan2
- STK31 | c.699C>T p.L233= | Silent (SNP) | VAF 23/416 reads (6%) | called by muse, mutect2
- TGFBI | c.1089G>A p.V363= | Silent (SNP) | VAF 24/343 reads (7%) | catalogued as rs760069077; called by muse, mutect2
- TIMD4 | c.780C>A p.L260= | Silent (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- TNS4 | c.2010C>A p.I670= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2
- TRPM1 | c.2283C>A p.I761= | Silent (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- TTYH3 | c.975G>T p.V325= | Silent (SNP) | VAF 36/222 reads (16%) | called by muse, mutect2, varscan2
- UNC79 | c.3076C>T p.L1026= (on ENST00000393151 / NM_001346218.2; = p.L849= on NM_020818.5) | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- UNC79 | c.5172A>G p.E1724= (on ENST00000393151 / NM_001346218.2; = p.E1547= on NM_020818.5) | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- VARS1 | c.546G>T p.R182= | Silent (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- WFDC1 | c.111G>C p.R37= | Silent (SNP) | VAF 23/203 reads (11%) | called by muse, mutect2, varscan2
- WFS1 | c.2214C>A p.A738= | Silent (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2
- ZFHX4 | c.1398C>A p.P466= | Silent (SNP) | VAF 36/400 reads (9%) | called by muse, mutect2
- ZNF423 | c.1140C>A p.P380= (on ENST00000563137 / NM_001379286.1; = p.P372= on NM_015069.4) | Silent (SNP) | VAF 34/369 reads (9%) | catalogued as COSV52204472; called by muse, mutect2
- ZNF536 | c.204C>A p.A68= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- ZNF718 | c.834T>G p.S278= | Silent (SNP) | VAF 7/125 reads (6%) | catalogued as COSV101210270; called by muse, mutect2
- ZNF830 | c.549G>T p.P183= | Silent (SNP) | VAF 26/338 reads (8%) | catalogued as rs746430524; called by muse, mutect2
- AC073264.3 | chr7:143620959 C>A | 5'Flank (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1344G>T | RNA (SNP) | VAF 16/89 reads (18%) | called by mutect2, varscan2
- ACSM2B | c.895-1338C>A | Intron (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- ANKRD33 | c.664+29C>A | Intron (SNP) | VAF 19/188 reads (10%) | called by muse, mutect2
- BOC | c.-112G>A | 5'UTR (SNP) | VAF 24/344 reads (7%) | called by muse, mutect2
- CLLU1 | chr12:92422562 G>T | 5'Flank (SNP) | VAF 16/204 reads (8%) | called by muse, mutect2
- CPED1 | c.2311-4574G>C | Intron (SNP) | VAF 50/504 reads (10%) | called by muse, mutect2
- DCHS2 | n.5663T>C | RNA (SNP) | VAF 14/321 reads (4%) | called by muse, mutect2
- DDX41 | c.*375C>A | 3'UTR (SNP) | VAF 42/449 reads (9%) | catalogued as rs768748580; called by muse, mutect2
- EIPR1 | c.516+5418G>T | Intron (SNP) | VAF 78/598 reads (13%) | called by muse, mutect2, varscan2
- EYS | c.1767-7308G>T | Intron (SNP) | VAF 66/902 reads (7%) | called by muse, mutect2
- EYS | c.1767-7875G>T | Intron (SNP) | VAF 56/687 reads (8%) | called by muse, mutect2
- FRMD8P1 | n.252G>T | RNA (SNP) | VAF 30/201 reads (15%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034990 A>T | 5'Flank (SNP) | VAF 12/185 reads (6%) | catalogued as rs1250304980; called by muse, mutect2
- GDAP1 | c.*2169T>A | 3'UTR (SNP) | VAF 8/157 reads (5%) | called by muse, mutect2
- GFUS | c.146+138G>T | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- HECW1 | c.4019+13975del | Intron (DEL) | VAF 13/94 reads (14%) | catalogued as rs1402882710; called by mutect2, pindel, varscan2
- HGF | c.89-34T>C | Intron (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- HRG | c.*34A>G | 3'UTR (SNP) | VAF 16/199 reads (8%) | called by muse, mutect2
- ITFG1 | c.560+1005G>T | Intron (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- MGP | c.62-641A>G | Intron (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- MIR510 | n.48T>C | RNA (SNP) | VAF 11/63 reads (17%) | catalogued as rs1041712363, CR096698; called by muse, mutect2, varscan2
- MMP16 | c.1222+5132C>A | Intron (SNP) | VAF 33/324 reads (10%) | catalogued as COSV54186069, COSV54189431; called by muse, mutect2, varscan2
- MMP16 | chr8:88327985 G>A | 5'Flank (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- MYL3 | chr3:46834004 del G | 3'Flank (DEL) | VAF 19/109 reads (17%) | called by mutect2, pindel, varscan2
- ORC6 | c.*387A>T | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- PDGFRA | c.2323+18C>G | Intron (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- PDLIM3 | c.94-25C>A | Intron (SNP) | VAF 36/839 reads (4%) | called by muse, mutect2
- PLCZ1 | c.949+9G>A | Intron (SNP) | VAF 53/553 reads (10%) | catalogued as COSV56852648; called by muse, mutect2
- PRICKLE2 | c.564+16G>A | Intron (SNP) | VAF 50/578 reads (9%) | catalogued as rs746187709; called by muse, mutect2
- RPS17 | c.-13A>G | 5'UTR (SNP) | VAF 54/701 reads (8%) | called by muse, mutect2
- SH2D6 | n.329+15G>A | Intron (SNP) | VAF 32/300 reads (11%) | called by muse, mutect2
- SLC35A4 | c.*42G>T | 3'UTR (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2
- SNX29 | c.2038-34690G>T | Intron (SNP) | VAF 12/257 reads (5%) | called by muse, mutect2
- SPATA8 | n.807G>A | RNA (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- SRL | c.62-2335C>A | Intron (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- ST3GAL6 | c.-289G>T | 5'UTR (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2
- STIMATE | c.160+1368T>C | Intron (SNP) | VAF 27/440 reads (6%) | catalogued as rs1176103766; called by muse, mutect2
- TMEM44 | c.924+535G>T | Intron (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- TRBV2 | c.-21C>A | 5'UTR (SNP) | VAF 48/458 reads (10%) | called by muse, mutect2, varscan2
- TTC26 | c.792+23G>T | Intron (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2, varscan2
- UAP1L1 | chr9:137086620 T>A | 3'Flank (SNP) | VAF 13/227 reads (6%) | called by muse, mutect2
- UEVLD | c.612+904C>T | Intron (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- XKR6 | c.764+137696G>T | Intron (SNP) | VAF 15/226 reads (7%) | called by muse, mutect2
- ZNF568 | c.*15T>C | 3'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
